Gene-level copy-number profile of tumor specimen TCGA-ZF-AA4T-01A from TCGA case TCGA-ZF-AA4T, project TCGA-BLCA (Bladder Urothelial Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Transitional cell carcinoma; Tissue or organ of origin: Bladder, NOS; AJCC pathologic stage: Stage IV; Tumor grade: High Grade; Age at diagnosis: 65.6 years (23,974 days).
Specimen TCGA-ZF-AA4T-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-BLCA.cf4db788-1a5f-4b30-ab04-fd7faf334cce.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-ZF-AA4T-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 812 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/1a85255f-9a82-4c85-b55a-933c30dcb457

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 12; copy number 1: 19,101; copy number 2: 19,412; copy number 3: 14,499; copy number 4: 4,899; copy number 5: 569; copy number 6: 645; copy number 7: 37; copy number 8: 134; copy number 9: 97; copy number 10: 136; copy number 11: 38; copy number 12: 41; copy number 13: 45; copy number 14: 53; copy number 16: 19; copy number 18: 42; copy number 21: 32.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-ZF-AA4T-01A-11D-A38F-01): tumor purity 0.39, ploidy 5.59, whole-genome doublings 2.

Homozygous deletions (total copy number 0; autosomes only): 12 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr18:25,818,234–25,818,532, 1 gene: RN7SL97P.
- chr18:37,243,040–37,565,827, 1 gene (within-gene range 0–3): CELF4.
- chr18:37,305,295–39,034,110, 9 genes: AC090386.2, AC129908.1, AC009899.1, MIR4318, RPL12P40, AC108452.1, AC100781.1, RN7SKP182, RNU6-706P.
- chr18:43,499,173–43,499,836, 1 gene: AC022743.1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 1,888 genes in 48 contiguous regions (the 40 largest listed; coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:150,363,091–150,881,683, 25 genes, copy number 9–10 (within-gene range 3–12): RPRD2, TARS2, MIR6878, ECM1, FALEC, ADAMTSL4-AS2, ADAMTSL4, MIR4257, ADAMTSL4-AS1, MCL1, RN7SL473P, RN7SL600P, AL356356.1, ENSA, U4, GOLPH3L, HORMAD1, RNU6-1042P, CTSS, AL356292.1, CTSK, UBE2D3P3, ARNT, RNU6-1309P, RPS27AP6.
- chr2:105,846,534–107,407,329, 28 genes, copy number 6: AC010978.1, AC009505.1, ECRG4, UXS1, AC018878.1, AC092106.1, RPL22P10, SRSF3P4, RPS21P2, RPL27AP4, ILRUNP1, AC114755.1, ANAPC1P6, PLGLA, RGPD3, AC097527.1, CD8B2, AC108868.2, AC108868.1, EEF1A1P12, ST6GAL2, ST6GAL2-IT1, AC016994.1, AC005040.2, PPP1R2P5, AC005040.1, LINC01789, AC096669.1.
- chr2:132,345,616–133,568,463, 15 genes, copy number 5 (within-gene range 4–5): AC097532.2, AC097532.3, FAM201B, RNU6-175P, GPR39, YBX1P7, RN7SKP103, LYPD1, AC010974.1, NCKAP5, AC010974.2, AC016909.1, NCKAP5-AS1, AC011755.1, NCKAP5-AS2.
- chr3:11,745–1,987,470, 20 genes, copy number 8: LINC01986, AC066595.1, CHL1-AS2, AC066595.2, CHL1, RNU6-1194P, RPS8P6, CHL1-AS1, AC087428.1, LINC01266, RPSAP32, AC090044.1, AC087430.1, RN7SL120P, CNTN6, CRB3P1, RPL23AP38, RPL23AP39, RPL21P17, AC018814.1.
- chr3:10,394,489–17,205,165, 137 genes, copy number 5–7 (broad region; genes not listed).
- chr3:17,333,126–17,665,025, 3 genes, copy number 5: AC090960.1, AC140076.1, RNU7-10P.
- chr3:88,317,156–90,261,708, 14 genes, copy number 5: ABCF2P1, CSNKA2IP, Y_RNA, NDUFA5P5, ICE2P2, GAPDHP50, EPHA3, AC109129.1, MTCO2P6, MTCO1P6, U3, RNU6-712P, PROS2P, HSPE1P19.
- chr4:32,351,038–33,693,993, 8 genes, copy number 5: LINC02353, AC116611.1, MAPRE1P2, AC093606.1, AC093878.1, AC097535.2, AC097535.1, AC079772.1.
- chr4:37,001,772–37,133,849, 2 genes, copy number 8 (within-gene range 4–8): LINC02616, AL136537.1.
- chr4:64,767,130–72,148,067, 145 genes, copy number 5 (broad region; genes not listed).
- chr5:20,606,710–21,779,522, 11 genes, copy number 6: LINC02146, LINC02241, AC138938.1, AC140168.1, AC140172.1, AC093274.1, GUSBP1, AC138951.1, AC138951.2, AC091946.2, AC091946.1.
- chr5:21,882,585–22,152,356, 3 genes, copy number 6: HSPD1P1, AC139497.1, PMCHL1.
- chr5:37,209,364–38,198,148, 19 genes, copy number 9: OFD1P17, RN7SL37P, AC025449.2, AC025449.1, NUP155, RNU7-75P, AC117532.1, WDR70, KCTD9P5, RNU6-1190P, RNU6-484P, GDNF-AS1, GDNF, LINC02117, AC008869.1, LINC02110, AC034226.1, LINC02119, AC010338.1.
- chr5:41,142,116–41,587,787, 3 genes, copy number 6: C6, PLCXD3, AC008817.1.
- chr5:44,495,099–45,895,970, 13 genes, copy number 6 (within-gene range 4–6): LINC02224, AC093292.1, RN7SL383P, MRPS30-DT, AC093297.1, MRPS30, AC093297.2, AC114954.1, AC116350.1, HCN1, AC117529.2, AC117529.1, AC122694.1.
- chr6:82,169,986–83,857,515, 18 genes, copy number 6–10 (within-gene range 2–10): IBTK, RNU6-130P, AL121977.1, AL121977.2, TPBG, UBE3D, LAP3P1, AL355613.1, DOP1A, PGM3, RWDD2A, ME1, AL391416.1, PRSS35, SNAP91, AL136972.1, AL139232.1, RIPPLY2.
- chr7:816,615–22,727,613, 326 genes, copy number 5–10 (within-gene range 1–10) (broad region; genes not listed).
- chr7:26,152,198–26,497,595, 8 genes, copy number 5: NFE2L3, HNRNPA2B1, CBX3, AC010677.2, AC010677.1, SNX10, AC004540.2, AC004540.1.
- chr7:47,275,154–47,948,466, 6 genes, copy number 6 (within-gene range 1–6): TNS3, LINC01447, C7orf65, PKD1L1, LINC00525, C7orf69.
- chr7:92,412,550–93,574,730, 22 genes, copy number 16–21 (within-gene range 3–21): TMBIM7P, AC007566.2, GATAD1, AC007566.1, ERVW-1, PEX1, RBM48, AC005156.1, FAM133B, CDK6, AC000065.2, AC000065.1, RNU6-10P, CDK6-AS1, RN7SL7P, SAMD9, SAMD9L, HEPACAM2, VPS50, CALCR, MIR653, MIR489.
- chr8:91,542,924–108,787,594, 316 genes, copy number 6 (within-gene range 4–6) (broad region; genes not listed).
- chr10:4,987,400–6,254,644, 49 genes, copy number 5: AKR1C2, AL391427.1, U8, AKR1C3, U8, AKR1C5P, AKR1C8P, AKR1C4, ARL4AP3, AL355303.2, AL355303.1, LINC02561, AKR1C7P, RPL26P28, AL683826.1, UCN3, TUBAL3, NET1, CALML5, CALML3-AS1, CALML3, AL732437.1, AL732437.3, AL732437.2, LASTR, AL365356.2, RN7SL445P, ASB13, TASOR2, AL365356.1, GDI2, NRBF2P5, AL596094.1, ANKRD16, RPL12P28, FBH1, AL137186.2, IL15RA, IL2RA, AL137186.3, AL137186.1, RPL32P23, RBM17, PFKFB3, RN7SKP78, MIR3155A, MIR3155B, AL157395.1, Y_RNA.
- chr10:7,818,505–12,169,961, 51 genes, copy number 11–21 (within-gene range 3–21): TAF3, GATA3, GATA3-AS1, AL390294.1, PRPF38AP1, LINC00708, AL390835.1, AC025946.1, AC025946.2, KRT8P37, CHCHD3P1, RNA5SP299, AL355333.1, LINC02676, AC044784.1, LINC00709, AL138773.1, HSP90AB7P, LINC02663, LINC02670, ELOCP3, Y_RNA, CUX2P1, AL354916.1, AL583859.1, CELF2-DT, AL583859.2, AL583859.3, AL136452.1, SFTA1P, CELF2, LINC00710, AL136369.2, AL136369.1, AL162408.1, CELF2-AS2, AL136320.1, CELF2-AS1, AC026887.1, USP6NL, AL512631.2, AL512631.1, ECHDC3, PROSER2, PROSER2-AS1, UPF2, RNU6-1095P, DHTKD1, RNU6-88P, SEC61A2, MIR548AK.
- chr11:32,052,843–36,598,279, 100 genes, copy number 7–14 (within-gene range 1–14) (broad region; genes not listed).
- chr11:46,677,080–47,642,607, 43 genes, copy number 5–9: ARHGAP1, ZNF408, F2, CKAP5, MIR5582, AC115088.1, SNORD67, LRP4-AS1, LRP4, AC021573.1, C11orf49, AC103792.1, AC090589.2, ARFGAP2, AC090589.3, PACSIN3, MIR6745, AC090589.1, DDB2, AC018410.1, ACP2, NR1H3, MADD, MADD-AS1, AC090582.1, MYBPC3, SPI1, AC090559.1, MIR4487, SLC39A13, PSMC3, RAPSN, CELF1, AC090559.2, RN7SL652P, NDUFS3, PTPMT1, KBTBD4, RNU5E-10P, KF459542.1, FAM180B, C1QTNF4, MTCH2.
- chr11:54,591,480–55,284,749, 15 genes, copy number 6–9 (within-gene range 2–9): OR4C50P, OR4C46, OR4C7P, OR4R2P, OR4A4P, OR4A3P, OR4A2P, OR4A8, OR4A7P, OR4A5, OR4A6P, TRIM48, AP005597.4, AP005597.3, AP005597.2.
- chr12:27,935,523–29,784,759, 26 genes, copy number 5–6 (within-gene range 4–6): AC008011.1, PTHLH, AC008011.2, CCDC91, AC022364.1, AC022364.2, AC022079.2, AC022079.1, RNU4-54P, RNA5SP355, AC084754.1, AC022081.1, AC024255.1, AC012150.1, FAR2, AC012150.2, AC009318.4, AC009318.1, AC009318.3, AC009318.2, ERGIC2, OVCH1-AS1, OVCH1, TMTC1, AC009320.1, RPL21P99.
- chr12:32,679,200–33,576,200, 19 genes, copy number 5: DNM1L, AC084824.2, Y_RNA, AC084824.5, AC084824.1, YARS2, AC084824.3, AC084824.4, AC087588.2, PKP2, AC087588.1, RPL35AP27, ASS1P14, AC087311.1, SYT10, AC023158.1, AC023158.2, AC016956.1, RNU6-400P.
- chr16:8,369,864–9,518,325, 30 genes, copy number 9–12 (within-gene range 4–12): AC018767.1, AC074052.1, AC074052.2, TMEM114, AC138420.1, METTL22, AC007224.2, ABAT, RN7SL743P, RNU7-63P, AC007224.1, TMEM186, PMM2, AC012173.1, AC022167.2, CARHSP1, AC022167.1, AC022167.4, LITAFD, USP7, AC022167.3, AC087190.2, C16orf72, AC087190.3, AC087190.1, RPL21P119, LINC02177, AC012178.1, LINC01177, LINC01195.
- chr17:19,203,825–20,009,234, 48 genes, copy number 8–9: AC106017.1, KYNUP3, EPN2, AC106017.2, EPN2-AS1, B9D1, MIR1180, AC124066.1, MAPK7, MFAP4, AC004448.5, RNF112, AC004448.3, AC004448.2, LINC02094, AC004448.4, RPS2P46, AC004448.1, SLC47A1, RPL17P43, SNORA59B, AC025627.1, SLC47A1P1, AC025627.2, AC025627.3, AC025627.4, MTND1P14, NMTRQ-TTG12-1, MTND2P12, MTCO1P39, SLC47A1P2, ALDH3A2, AC115989.1, Y_RNA, AC005722.2, SLC47A2, AC005722.3, AC005722.4, ALDH3A1, AC005722.1, ULK2, NDUFB4P3, AC015726.3, AC015726.2, AC015726.1, AKAP10, AC005730.3, AC005730.2.
- chr17:38,530,031–39,451,272, 49 genes, copy number 10–13: SRCIN1, AC006449.1, EPOP, MIR4734, AC006449.6, AC006449.2, MLLT6, AC006449.3, MIR4726, AC006449.7, CISD3, RNA5SP440, PCGF2, AC006449.5, PSMB3, RNU6-866P, PIP4K2B, CWC25, MIR4727, C17orf98, RPL23, SNORA21B, SNORA21, AC110749.1, LASP1, AC006441.1, MIR6779, AC006441.3, LINC00672, FBXO47, AC006441.2, AC006441.4, AC006441.5, LINC02079, LRRC37A11P, AC091178.1, RDM1P5, PLXDC1, AC091178.2, ARL5C, AC004408.2, AC004408.1, CACNB1, RPL19, STAC2, AC015910.1, FBXL20, AC005288.1, MED1.
- chr17:39,637,090–39,864,312, 11 genes, copy number 21: STARD3, TCAP, PNMT, PGAP3, ERBB2, MIR4728, MIEN1, GRB7, IKZF3, KRT8P34, AC090844.1.
- chr18:1,883,524–3,478,978, 39 genes, copy number 18 (within-gene range 4–18): AP005230.1, AIDAP3, AP005136.4, METTL4, AP005136.1, AP005136.3, AP005136.2, NDC80, KATNBL1P3, Y_RNA, RNU6-340P, CBX3P2, SMCHD1, AP001011.1, Y_RNA, EMILIN2, LPIN2, AP000919.3, CHORDC1P4, AP000919.1, AP000919.2, SNRPCP4, AP005431.1, SNORA70, MYOM1, RNU7-25P, AP005329.2, AP005329.3, MYL12A, AP005329.1, MYL12B, AP001025.1, LINC01895, RPL31P59, IGLJCOR18, RPL21P127, TGIF1, BOD1P1, GAPLINC.
- chr18:3,571,215–3,598,363, 3 genes, copy number 18: RN7SL39P, AP002472.1, DLGAP1-AS1.
- chr18:6,601,540–9,679,493, 62 genes, copy number 5 (broad region; genes not listed).
- chr18:12,738,965–15,330,282, 88 genes, copy number 8–11 (broad region; genes not listed).
- chr18:44,970,082–46,266,992, 24 genes, copy number 10 (within-gene range 2–10): MIR4319, AC105074.1, AC090376.1, SLC14A2, SLC14A2-AS1, AC021517.1, AC021517.3, AC091151.2, AC091151.7, AC091151.1, AC023421.1, AC023421.2, SLC14A1, AC087685.1, SIGLEC15, EPG5, PSTPIP2, RN7SKP26, AC012569.1, RNY4P37, ATP5F1A, HAUS1, RNU6-1278P, C18orf25.
- chr18:48,475,487–48,479,228, 3 genes, copy number 14: RNA5SP456, AC024288.1, POLR3GP2.
- chr18:76,822,557–77,650,973, 19 genes, copy number 5: ZNF236, RPL26P35, Metazoa_SRP, AC027575.1, AC093330.1, MBP, AC093330.2, AC093330.3, AC018529.1, AC018529.3, AC018529.2, AC100863.1, GALR1, AC124254.2, AC124254.1, BDP1P, AC123786.1, AC123786.2, AC123786.3.
- chr21:22,882,582–26,573,286, 58 genes, copy number 5–7: AP000949.1, AP001116.1, MIR6130, ZNF299P, MSANTD2P1, AP001255.1, RNU2-55P, D21S2088E, EEF1A1P1, TUBAP1, Y_RNA, AP000459.1, AP000961.1, AP000474.2, AP000474.1, AP000477.2, AP000477.3, AP000477.1, AP000470.1, LINC01689, LINC01684, LINC01692, AP000402.1, AP000146.1, AP001342.1, AP000235.1, AP000233.2, RN7SKP236, AP000233.1, AP001341.1, RNA5SP489, RPL13AP7, AP001340.1, LINC00158, AP000221.1, MIR155HG, MIR155, AP000223.1, MRPL39, JAM2, RNGTTP1, AP000224.1, FDX1P2, ATP5PF, GABPA, LLPHP2, APP, AP001442.1, RNU6-123P, AP001439.1, AP000229.1, RNU6-926P, AP001595.2, AP001595.1, AP001596.1, CYYR1-AS1, AP001596.2, CYYR1.

Autosomal genes at a single copy (total copy number 1): 17,640. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
